CPTAC case C3L-02650 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8767d970-812a-4828-aaa1-0b9ff956dffc

Demographics
Sex at birth: male; Race: white; Year of birth: 1965; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 53.2 years (19,414 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,422 days (3.9 years); Progression or recurrence: no; Days to last follow up: 1,422 days (3.9 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 8 cm (a second GDC size field records 6 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 479 days (1.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 805 days (2.2 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,024 days (2.8 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,024 days (2.8 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,422 days (3.9 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 95 kg; Height: 175 cm; BMI: 31.02; Diabetes treatment type: Insulin; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02650-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 335 mg; Time between clamping and freezing: 29 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02650-26: Section location: Right lung; Percent tumor nuclei: 65; Percent necrosis: 15.
- Sample C3L-02650-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 412 mg; Time between clamping and freezing: 30 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02650-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
